Gene-level copy-number profile of tumor specimen ALCH-B4RW-TTP1-A from ALCHEMIST case ALCH-B4RW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.2 years (30,039 days).
Specimen ALCH-B4RW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 230455d6-b6c3-483b-840d-95768bf7d38a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4RW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/3feac797-2e63-4002-8ce3-cb86eb6dc33c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 81; copy number 1: 5,750; copy number 2: 45,850; copy number 3: 5,806; copy number 4: 259; copy number 5: 260; copy number 6: 101; copy number 7: 174; copy number 8: 93; copy number 9: 11; copy number 10: 11; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,812,265–21,825,225, 1 gene (within-gene range 0–1): LDLRAD2.
- chr3:50,205,246–50,221,486, 1 gene: SLC38A3.
- chr7:102,264,706–102,321,711, 3 genes (within-gene range 0–1): AC005088.1, SH2B2, MIR4285.
- chr8:41,828,165–41,840,339, 2 genes (within-gene range 0–1): AC027702.1, RN7SL149P.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:130,444,961–130,501,274, 1 gene: ASS1.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr14:73,237,497–73,274,640, 4 genes (within-gene range 0–2): PAPLN, AC004846.1, RNU6-419P, AC004846.2.
- chr14:100,143,957–100,159,645, 1 gene (within-gene range 0–2): DEGS2.
- chr15:25,180,497–25,249,279, 38 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43.
- chr16:2,106,669–2,113,342, 2 genes (within-gene range 0–1): MIR6511B1, AC009065.6.
- chr16:87,683,945–87,696,147, 2 genes (within-gene range 0–2): AC010536.3, AC010536.1.
- chr17:7,380,534–7,394,842, 2 genes (within-gene range 0–1): TNK1, PLSCR3.
- chr17:9,244,666–9,244,897, 1 gene: AC005695.3.
- chr17:82,078,338–82,098,294, 1 gene: FASN.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–2): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr19:3,473,986–3,480,525, 1 gene: SMIM24.
- chr19:49,047,638–49,058,860, 3 genes (within-gene range 0–2): CGB8, AC008687.6, CGB7.
- chr19:49,056,088–49,058,761, 1 gene (within-gene range 0–2): AC008687.7.
- chr19:50,415,799–50,428,409, 1 gene (within-gene range 0–2): AC020909.1.
- chr22:38,734,725–38,794,143, 7 genes (within-gene range 0–2): AL021707.5, SUN2, AL021707.3, AL021707.8, AL021707.1, AL021707.6, AL021707.7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 651 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:8,182,072–10,054,936, 76 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr4:16,360,686–18,021,876, 20 genes, copy number 6: ZEB2P1, AC097515.1, LDB2, AC104656.1, AC106894.1, MTND5P4, LINC02493, SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, LAP3, AC006160.1, MED28, FAM184B, DCAF16, NCAPG, LCORL, KRT18P63.
- chr4:24,658,072–24,671,568, 2 genes, copy number 5: ATP5MGP3, LINC02473.
- chr4:28,711,198–28,711,476, 1 gene, copy number 5: RN7SL101P.
- chr5:58,198–1,345,099, 48 genes, copy number 7–11: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L.
- chr5:1,392,794–1,445,440, 1 gene, copy number 7: SLC6A3.
- chr5:1,544,107–4,866,311, 42 genes, copy number 5–10 (within-gene range 2–10): AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1.
- chr5:4,967,764–6,022,283, 16 genes, copy number 5: AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC010266.2.
- chr5:8,785,042–9,045,940, 5 genes, copy number 6 (within-gene range 2–6): AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1.
- chr5:12,297,399–12,297,504, 1 gene, copy number 6: RNU6-679P.
- chr5:15,110,786–15,266,541, 2 genes, copy number 6: U8, LINC02149.
- chr17:48,762,235–48,817,214, 1 gene, copy number 5 (within-gene range 4–5): TTLL6.
- chr17:48,831,018–51,336,240, 127 genes, copy number 5–7 (broad region; genes not listed).
- chr17:58,301,228–59,950,574, 61 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:62,231,470–65,056,740, 125 genes, copy number 5–7 (broad region; genes not listed).
- chr17:68,101,908–69,903,000, 42 genes, copy number 5: LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1.
- chr17:71,596,338–75,065,889, 81 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,750. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
